Somatic mutation profile of tumor specimen TCGA-55-A48X-01A (aliquot TCGA-55-A48X-01A-11D-A24D-08) from TCGA case TCGA-55-A48X, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.9 years (23,341 days).
Specimen TCGA-55-A48X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aee0fff-4d4b-4074-96ce-0f78c3a8810a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A48X-10A (Blood Derived Normal), aliquot TCGA-55-A48X-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/debfd306-2fa3-4675-a9a0-dd4db98010a9

The open-access MAF lists 395 somatic variants for this specimen: 308 protein-altering or splice-affecting, 78 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 78, Nonsense Mutation 28, Splice Site 6, Splice Region 5, Intron 4, Frame Shift Del 3, Frame Shift Ins 2, 3'Flank 2, RNA 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.3904G>A p.G1302R (on ENST00000372530 / NM_001198934.2; = p.G1274R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99767831; called by muse, mutect2, varscan2
- ABCC8 | c.3989-1G>T p.X1330_splice | Splice Site (SNP) | VAF 24/138 reads (17%) | catalogued as COSV100217623; called by muse, mutect2, varscan2
- ACSF3 | c.972A>T p.K324N | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV100441511; called by muse, mutect2, varscan2
- ACSM5 | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100089406; called by muse, mutect2
- ADAMTS19 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50772877, COSV99180042; called by muse, mutect2, varscan2
- ADAMTS8 | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99961438; called by muse, mutect2, varscan2
- ADCY1 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV99812744; called by muse, mutect2, varscan2
- ADGRA3 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs756669320, COSV99293699; called by mutect2, varscan2
- ADGRG4 | c.3445C>A p.P1149T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54968882, COSV99796386; called by muse, mutect2
- AGMO | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV100694615; called by muse, mutect2, varscan2
- AHNAK | c.13351G>A p.E4451K | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.619); catalogued as COSV99949042; called by muse, mutect2, varscan2
- ALDH3A1 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856014; called by muse, mutect2, varscan2
- ALDH3A2 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99450165; called by muse, mutect2, varscan2
- AMY2B | c.1271G>T p.W424L | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796456; called by muse, mutect2, varscan2
- ANK2 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV100003567; called by muse, mutect2, varscan2
- ANK2 | c.8693C>A p.T2898N | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV100003574; called by muse, mutect2
- ANKRD17 | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.395); catalogued as COSV100429816; called by mutect2, varscan2
- ANKRD50 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV101539019; called by muse, mutect2
- ANO1 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100304380; called by muse, mutect2
- AOX1 | c.3814G>C p.G1272R | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs748330656, COSV99613760; called by muse, mutect2, varscan2
- ARHGEF6 | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV99166639; called by muse, mutect2, varscan2
- ARID1B | c.3899G>C p.S1300T | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99271288; called by muse, mutect2, varscan2
- ARRDC2 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.962); catalogued as COSV99716932; called by muse, mutect2, varscan2
- ASTN1 | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.152); catalogued as COSV100707589; called by muse, mutect2
- ATG2A | c.3116A>T p.Q1039L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV101034719; called by muse, mutect2, varscan2
- ATG2A | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101034720; called by muse, mutect2
- ATP4A | c.2080C>G p.R694G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV52867497; called by muse, mutect2
- B3GNT3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427626; called by muse, mutect2, varscan2
- BTK | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV100437658, COSV100437838; called by muse, mutect2, varscan2
- BTK | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV58120655; called by muse, mutect2
- C1orf87 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1389820752, COSV100966859, COSV100967220, COSV64596320; called by muse, mutect2, varscan2
- C4orf50 | c.680G>T p.G227V (on ENST00000324058; = p.G1459V on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as COSV100136096, COSV60688430; called by muse, mutect2, varscan2
- C6orf118 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100024953; called by muse, mutect2, varscan2
- C9 | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.492); catalogued as COSV99662405; called by muse, mutect2, varscan2
- CACNA1F | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as rs782074040, CM055909, COSV100545278; called by muse, mutect2, varscan2
- CALB2 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV56941901; called by muse, mutect2, varscan2
- CAPN6 | c.1143C>A p.F381L | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100137019; called by muse, mutect2, varscan2
- CASD1 | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as COSV99802957; called by muse, mutect2
- CASP9 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV100423914; called by muse, mutect2, varscan2
- CCNB3 | c.2237A>T p.Q746L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.521); catalogued as COSV99329606; called by muse, mutect2
- CCT4 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV101075350; called by muse, mutect2, varscan2
- CCT8L2 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100743034; called by muse, mutect2
- CD99L2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV100692471; called by muse, mutect2
- CDH9 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV50374477, COSV99147166; called by muse, mutect2, varscan2
- CFAP251 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99996382; called by muse, mutect2, varscan2
- CFAP47 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs1029862441, COSV52884611; called by muse, mutect2
- CFAP47 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99935684; called by muse, mutect2
- CFAP47 | c.4580C>A p.T1527K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV100545475; called by muse, varscan2
- CLIC5 | c.986G>A p.G329E (on ENST00000185206 / NM_001370649.1; = p.G170E on NM_016929.5) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99485207; called by muse, mutect2, varscan2
- CNGA1 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV100652307; called by muse, mutect2, varscan2
- CNOT6L | c.126G>T p.S42= (on ENST00000504123 / NM_001286790.2; = p.S37= on NM_144571.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99362146; called by muse, mutect2, varscan2
- CNST | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100829907; called by muse, mutect2, varscan2
- COBL | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99473798; called by muse, mutect2, varscan2
- COL5A2 | c.1771-1G>T p.X591_splice | Splice Site (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100880676; called by muse, mutect2, varscan2
- CSNK1G3 | c.545A>T p.H182L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100631709; called by muse, varscan2
- CTCFL | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs769334115, COSV54774006; called by muse, mutect2, varscan2
- CYB561D1 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV100149920; called by muse, varscan2
- CYC1 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010550; called by muse, mutect2, varscan2
- DENND5A | c.3055G>T p.G1019W | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100065123; called by muse, mutect2, varscan2
- DGKB | c.1584T>G p.D528E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342521; called by muse, mutect2, varscan2
- DGKI | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV99936724; called by muse, mutect2
- DIDO1 | c.6007G>A p.E2003K | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV56630973, COSV99826785; called by muse, mutect2, varscan2
- DNAH8 | c.9505G>T p.D3169Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100546826; called by muse, mutect2, varscan2
- DNAH9 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99307535; called by muse, mutect2, varscan2
- DNAJB9 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99974571; called by muse, mutect2, varscan2
- DNAJC10 | c.1745A>G p.D582G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1211303875, COSV99899541; called by muse, mutect2, varscan2
- DNAJC3 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV100953445; called by muse, mutect2, varscan2
- DNASE1L1 | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99186261; called by muse, mutect2, varscan2
- DOCK11 | c.4084G>A p.V1362I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99354502; called by muse, mutect2
- DPP6 | c.271A>T p.R91W (on ENST00000377770 / NM_001364500.2; = p.R29W on NM_001936.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100127520; called by muse, mutect2, varscan2
- DPYSL5 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99982700; called by muse, mutect2, varscan2
- DYNC1H1 | c.2105G>A p.W702* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100795272; called by muse, mutect2, varscan2
- DYNC1H1 | c.2106G>T p.W702C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795274; called by muse, mutect2, varscan2
- EFCAB6 | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99414170; called by muse, mutect2
- EMD | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100877405; called by muse, mutect2, varscan2
- ENGASE | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1307647725, COSV100285918; called by muse, mutect2
- ENPEP | c.1701C>A p.N567K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV99488021; called by muse, mutect2, varscan2
- EPHB4 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639617, COSV62267789; called by muse, mutect2, varscan2
- EPRS1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV100859464; called by muse, mutect2, varscan2
- EPS8L1 | c.1650G>A p.L550= (on ENST00000201647 / NM_133180.3; = p.L423= on NM_017729.3) | Splice Region (SNP) | VAF 13/70 reads (19%) | catalogued as COSV52385990; called by muse, mutect2, varscan2
- ERCC3 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 57/401 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99573616; called by muse, mutect2, varscan2
- ERICH1 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100032897; called by muse, mutect2, varscan2
- EVPL | c.4119G>T p.Q1373H | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV101440963; called by muse, mutect2, varscan2
- EWSR1 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.347); catalogued as rs758074601, COSV100131993; called by muse, mutect2, varscan2
- FAM47C | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100792904; called by muse, mutect2
- FAM47C | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100792905, COSV63729110; called by muse, mutect2
- FAM78A | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.03); catalogued as rs371500291, COSV55992871; called by muse, mutect2
- FAT3 | c.12809C>A p.S4270* | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | catalogued as COSV99969672; called by muse, mutect2, varscan2
- FBXL20 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99234617, COSV99234661; called by muse, mutect2, varscan2
- FBXW9 | c.1358A>T p.N453I (on ENST00000587955; = p.N433I on NM_032301.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100982058, COSV66710176; called by mutect2, varscan2
- FDPS | c.832G>C p.A278P | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV100756267; called by muse, mutect2, varscan2
- FERD3L | c.500G>T p.*167Lext*? | Nonstop Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99285050; called by muse, mutect2, varscan2
- FGFR2 | c.565A>C p.M189L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100337004; called by muse, mutect2, varscan2
- FHL5 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100459673; called by muse, mutect2, varscan2
- FLNA | c.1819G>T p.G607C | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775058; called by muse, mutect2
- FMO3 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV100882534; called by muse, mutect2, varscan2
- FNDC1 | c.1654T>A p.S552T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV99796491; called by muse, mutect2, varscan2
- FOXS1 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99640158; called by muse, mutect2
- FTMT | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV100360426; called by muse, mutect2
- FUT9 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV100132812, COSV100134133; called by muse, mutect2, varscan2
- GAB4 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV101272078; called by muse, mutect2, varscan2
- GABRA1 | c.977C>A p.S326* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99196197; called by muse, mutect2, varscan2
- GBP4 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV100864450; called by muse, mutect2, varscan2
- GBP5 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs751275007, COSV100599947; called by muse, mutect2, varscan2
- GFRAL | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475742, COSV61229837; called by muse, mutect2, varscan2
- GLIS3 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100174615; called by muse, mutect2, varscan2
- GLMP | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as COSV99828066; called by muse, mutect2
- GLMP | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99828068; called by muse, mutect2
- GLS2 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100358435; called by muse, mutect2
- GNAL | c.767C>A p.S256Y (on ENST00000269162 / NM_001142339.3; = p.S333Y on NM_182978.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99304038; called by muse, mutect2, varscan2
- GPR174 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV99338329; called by muse, mutect2, varscan2
- GPRASP1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV100851059; called by muse, mutect2, varscan2
- GRM5 | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100553876; called by muse, mutect2
- HCFC1 | c.2053T>A p.S685T | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV100129714; called by muse, mutect2
- HCFC1 | c.1100C>A p.P367Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129717; called by muse, mutect2
- HCFC1 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129718; called by muse, mutect2
- HCK | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs146996549; called by muse, mutect2, varscan2
- HDC | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99984264; called by muse, mutect2, varscan2
- HOXB3 | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100290789; called by muse, mutect2
- IARS2 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100228554; called by muse, mutect2, varscan2
- IFNG | c.366+1G>T p.X122_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99971260; called by muse, varscan2
- IFNG | c.366G>T p.S122= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as COSV57490634, COSV99971261; called by muse, mutect2, varscan2
- IGSF5 | c.720C>T p.D240= | Splice Region (SNP) | VAF 5/64 reads (8%) | catalogued as COSV101012126; called by muse, mutect2
- ITGA7 | c.2482T>A p.L828M (on ENST00000555728; = p.L784M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV99151454; called by muse, mutect2, varscan2
- ITIH3 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99819763; called by muse, mutect2, varscan2
- ITPRID1 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as COSV100086234, COSV100087273; called by muse, mutect2
- KANSL1 | c.1174A>T p.R392W | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52266991; called by muse, mutect2
- KAZN | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101056924; called by muse, mutect2, varscan2
- KCNA4 | c.1956T>A p.D652E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.306); catalogued as COSV100069205; called by muse, mutect2, varscan2
- KCNH6 | c.2226C>A p.N742K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100121215; called by muse, mutect2
- KCNK5 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV100851914; called by muse, mutect2, varscan2
- KEL | c.945C>A p.D315E | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100787265; called by muse, mutect2, varscan2
- KRT16 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV100053019; called by muse, mutect2, varscan2
- KRT4 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99543156; called by muse, mutect2, varscan2
- KRTAP19-4 | c.133G>T p.G45* | Nonsense Mutation (SNP) | VAF 23/197 reads (12%) | catalogued as COSV100478565; called by muse, mutect2, varscan2
- KRTAP21-1 | c.229T>G p.S77A | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV100624954; called by muse, varscan2
- L1CAM | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649424; called by muse, mutect2
- L1CAM | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as COSV62830309; called by muse, mutect2
- LAMA1 | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101057421; called by muse, mutect2, varscan2
- LGI3 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.478); catalogued as COSV100103252; called by muse, mutect2, varscan2
- LGMN | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as rs202247404, COSV100605955, COSV58403066; called by muse, mutect2, varscan2
- LGR6 | c.213-2A>G p.X71_splice (on ENST00000367278 / NM_001017403.1; = p.X19_splice on NM_021636.3) | Splice Site (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99707682; called by muse, mutect2, varscan2
- LONRF3 | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV100504601; called by muse, mutect2, varscan2
- LSG1 | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV99503478; called by muse, mutect2, varscan2
- MAN1A2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100741028; called by muse, mutect2, varscan2
- MANBA | c.1034T>G p.I345S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs976246560, COSV99899079; called by muse, mutect2
- MAP3K6 | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV100709098, COSV100709404; called by muse, mutect2, varscan2
- MAP4K2 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99581534; called by muse, mutect2, varscan2
- MCM6 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.456); catalogued as COSV99072120, COSV99919324; called by muse, mutect2, varscan2
- MED13L | c.4673C>T p.A1558V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99929869; called by muse, mutect2, varscan2
- MED13L | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1248970090, COSV99929871; called by muse, mutect2
- MKRN1 | c.545-1G>T p.X182_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99751838; called by muse, mutect2
- MMP16 | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54153161, COSV99689912; called by muse, mutect2, varscan2
- MRPL3 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV99394970, COSV99394992; called by muse, mutect2, varscan2
- MRPL3 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99394995; called by muse, mutect2, varscan2
- MTARC1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs144239231, COSV100856346; called by muse, mutect2, varscan2
- MTREX | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100044424; called by muse, mutect2, varscan2
- MTUS1 | c.3178G>T p.E1060* (on ENST00000262102 / NM_001363061.1; = p.E226* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99870544; called by muse, mutect2, varscan2
- MYBPC3 | c.3031G>A p.G1011R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs756480912, COSV99920877; called by muse, mutect2
- MYH2 | c.4397G>C p.C1466S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99820745; called by muse, mutect2
- MYMK | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.949); catalogued as COSV101301170; called by muse, mutect2, varscan2
- MYO15A | c.10273A>T p.S3425C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99234070; called by muse, mutect2, varscan2
- MYO5B | c.3497A>C p.Q1166P | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV99546063; called by muse, mutect2
- MYOM1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as rs777236126, COSV99867976; called by muse, mutect2, varscan2
- MYOZ2 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100201833, COSV61084484; called by muse, mutect2
- NCAN | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV53052036; called by muse, mutect2, varscan2
- NFASC | c.2535G>T p.W845C (on ENST00000339876 / NM_001378329.1; = p.W948C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100365278; called by mutect2, varscan2
- NFRKB | c.1386C>T p.G462= (on ENST00000446488 / NM_001143835.2; = p.G487= on NM_006165.3) | Splice Region (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100452058; called by muse, mutect2, varscan2
- NHS | c.2155C>A p.P719T | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101196905; called by muse, mutect2
- NOX3 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV99343576; called by muse, mutect2
- NPBWR1 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100488278; called by muse, mutect2
- NPPA | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1234635947, COSV100412142; called by muse, mutect2, varscan2
- NPY2R | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.013); catalogued as rs1189039963, COSV61527228, COSV61528234; called by muse, mutect2, varscan2
- NT5C2 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100583675; called by muse, mutect2, varscan2
- OLFM3 | c.1314C>A p.Y438* (on ENST00000338858 / NM_001288821.1; = p.Y418* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV100129941, COSV58804827; called by muse, mutect2, varscan2
- OR13C4 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV99470271; called by muse, mutect2, varscan2
- OR2A2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as rs1563048193, COSV101286667, COSV68871403; called by muse, mutect2, varscan2
- OR2F2 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV101283841; called by muse, mutect2
- OR2M3 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV101513504; called by muse, mutect2, varscan2
- OR2M5 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100822862; called by muse, mutect2, varscan2
- OR2W3 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 41/171 reads (24%) | catalogued as COSV100831799; called by muse, mutect2, varscan2
- OR4C12 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100078641; called by muse, mutect2, varscan2
- OR4K13 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100237856; called by muse, mutect2, varscan2
- OR51E2 | c.718T>A p.C240S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211387; called by muse, mutect2
- OR52E8 | c.524G>T p.C175F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101190805, COSV66211100; called by muse, mutect2
- OR5AR1 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV100265756; called by muse, mutect2, varscan2
- OR5H1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100641647, COSV100641757; called by muse, mutect2, varscan2
- OR5T3 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100282896; called by muse, mutect2, varscan2
- OR8B2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV100899475, COSV66665052; called by muse, mutect2
- OXA1L | c.65T>C p.L22S | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99591278; called by muse, mutect2, varscan2
- P2RY10 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99409055; called by muse, mutect2, varscan2
- PALD1 | c.2256C>G p.Y752* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99698317, COSV99698577; called by muse, mutect2
- PAMR1 | c.1241G>A p.C414Y (on ENST00000619888 / NM_001001991.3; = p.C431Y on NM_015430.4) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553106; called by muse, mutect2, varscan2
- PCDH15 | c.868A>T p.R290* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as CM064160, COSV100226000; called by muse, mutect2, varscan2
- PCDHAC1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782141467, COSV99169274; called by muse, mutect2, varscan2
- PCDHB3 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV99166334; called by muse, mutect2
- PCDHB4 | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV99522448; called by muse, mutect2, varscan2
- PCDHGA5 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV99544738; called by muse, mutect2, varscan2
- PDCD11 | c.2104G>T p.V702F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100874405; called by muse, mutect2, varscan2
- PDS5A | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100337521; called by muse, mutect2, varscan2
- PEG3 | c.2758G>T p.G920C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99690064; called by muse, mutect2, varscan2
- PER3 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100728443; called by muse, mutect2, varscan2
- PGLYRP3 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs1323462476, COSV99319895; called by muse, mutect2, varscan2
- PKNOX2 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100021655; called by muse, mutect2
- PLEKHA7 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100850386; called by muse, mutect2, varscan2
- PLEKHM3 | c.1963A>T p.K655* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101216813; called by muse, mutect2
- POTEH | c.482A>T p.D161V | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100625176; called by muse, mutect2
- PPFIA3 | c.3412G>T p.D1138Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99418236; called by muse, mutect2, varscan2
- PPIAL4G | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV101344022; called by mutect2, varscan2
- PRKD3 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99306602; called by muse, mutect2, varscan2
- PRORP | c.1482G>T p.R494S | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs1247551514, COSV51617240; called by muse, mutect2, varscan2
- PRR27 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100748887; called by muse, mutect2, varscan2
- PRR27 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60640280; called by muse, mutect2, varscan2
- PSG9 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568421939, COSV99392512; called by muse, mutect2, varscan2
- PTCH2 | c.2260C>A p.R754S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV100942252; called by muse, mutect2, varscan2
- PXDNL | c.2287G>T p.A763S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100685661; called by muse, mutect2
- QSOX1 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100852936; called by muse, mutect2, varscan2
- RALGAPB | c.873-2A>T p.X291_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99485634; called by muse, mutect2, varscan2
- RAPGEF2 | c.907A>T p.R303W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031540; called by muse, mutect2
- RAPGEF4 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV51381089, COSV99911371; called by muse, mutect2, varscan2
- RBM18 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101313795; called by muse, mutect2, varscan2
- RBM27 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99506523; called by muse, mutect2
- RDH8 | c.640G>A p.G214R (on ENST00000651512; = p.G194R on NM_015725.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99408783; called by mutect2, varscan2
- RHBDF1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99245024; called by muse, mutect2, varscan2
- RHOXF1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.193); catalogued as COSV99483818, COSV99483900; called by muse, mutect2, varscan2
- RNASE13 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as COSV100409637; called by muse, mutect2, varscan2
- RPL10L | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV53558822, COSV53559285; called by muse, mutect2
- RPS6KA3 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101084608; called by muse, mutect2
- RPS6KA3 | c.1545G>T p.E515D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV101084610; called by muse, mutect2
- RPS6KL1 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100665185; called by muse, mutect2, varscan2
- SACS | c.5909G>A p.G1970E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV101207662; called by muse, mutect2, varscan2
- SCAF4 | c.2594T>A p.M865K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99532246; called by muse, mutect2, varscan2
- SCN3B | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54798131; called by muse, mutect2
- SCN4A | c.4400G>T p.G1467V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV101438620; called by muse, mutect2, varscan2
- SEMA5A | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101228645; called by muse, mutect2
- SEPTIN14 | c.352C>G p.Q118E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV101193412; called by muse, mutect2, varscan2
- SH3BP2 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.328); catalogued as COSV100697030; called by muse, mutect2
- SIGLEC6 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV100585622; called by muse, mutect2, varscan2
- SLC10A4 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99906976; called by muse, mutect2
- SLC12A5 | c.625C>A p.L209M (on ENST00000454036 / NM_001134771.2; = p.L186M on NM_020708.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99716626; called by muse, mutect2, varscan2
- SLC17A9 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV100947974; called by muse, mutect2, varscan2
- SLC30A8 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101438737; called by muse, mutect2, varscan2
- SLITRK2 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100158116; called by muse, mutect2, varscan2
- SLITRK4 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs868983945, COSV62022882; called by muse, mutect2, varscan2
- SNAI1 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV99724003; called by muse, mutect2
- SNCAIP | c.2602A>G p.M868V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV54424999; called by muse, mutect2
- SPDL1 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1250473040, COSV54666930; called by muse, mutect2, varscan2
- SPECC1 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99822634; called by muse, mutect2, varscan2
- SPPL2A | c.220A>C p.N74H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99961774; called by muse, mutect2, varscan2
- SPPL2C | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234132; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.448A>T p.R150W | Missense Mutation (SNP) | VAF 40/209 reads (19%) | PolyPhen possibly damaging (0.715); catalogued as COSV99336611; called by muse, mutect2, varscan2
- ST8SIA4 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | PolyPhen benign (0.198); catalogued as COSV51506000; called by muse, mutect2, varscan2
- STAG1 | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99366663; called by muse, mutect2, varscan2
- SULF2 | c.1102A>T p.T368S | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100737380, COSV63414548; called by muse, mutect2, varscan2
- SYNE2 | c.18958G>A p.V6320M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1378623200, COSV100648346; called by muse, mutect2
- TAF1 | c.4037A>G p.Y1346C (on ENST00000373790 / NM_138923.4; = p.Y1367C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99336732; called by muse, mutect2, varscan2
- TBR1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV101271519; called by muse, mutect2, varscan2
- TDRD7 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.896); catalogued as COSV100795774; called by muse, mutect2, varscan2
- TENM1 | c.992C>G p.A331G | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV100950626; called by muse, mutect2, varscan2
- TFEB | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV100026074; called by muse, mutect2, varscan2
- TG | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99602668; called by muse, mutect2, varscan2
- TGIF2LX | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99383493; called by muse, mutect2
- TIAM1 | c.1886A>C p.Q629P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99738143; called by muse, mutect2, varscan2
- TIMELESS | c.2110G>T p.V704F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV57508832, COSV99974254; called by muse, mutect2, varscan2
- TKTL1 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV54214674, COSV99474124; called by muse, mutect2, varscan2
- TKTL1 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV99474125; called by muse, mutect2
- TLN2 | c.5651G>A p.G1884E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100169842; called by muse, mutect2
- TLR7 | c.2650C>A p.L884I | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as COSV101028087; called by muse, mutect2, varscan2
- TMCO6 | c.478A>T p.S160C | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99347315; called by muse, mutect2, varscan2
- TMEM248 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100447293, COSV100447454; called by muse, mutect2
- TMEM38B | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.688); catalogued as COSV101016554; called by muse, mutect2, varscan2
- TMPRSS15 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV53042235; called by muse, mutect2, varscan2
- TNXB | c.9124G>T p.E3042* (on ENST00000647633; = p.E2795* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV64481441; called by muse, mutect2, varscan2
- TRHR | c.70T>A p.Y24N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100305042; called by muse, mutect2, varscan2
- TRIM25 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV100381103; called by muse, mutect2
- TSHR | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.228); catalogued as COSV99992577; called by muse, mutect2, varscan2
- TSHZ3 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99552449; called by muse, mutect2, varscan2
- TTC30B | c.424A>T p.R142W | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV101282804; called by muse, mutect2, varscan2
- TUBA3C | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1350985697, COSV101262822; called by muse, mutect2, varscan2
- UGT1A6 | c.1485G>C p.L495F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100530784; called by muse, mutect2, varscan2
- UGT2B11 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs775064565, COSV71423283; called by muse, mutect2, varscan2
- USP31 | c.3386C>G p.S1129C | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); catalogued as COSV99565712; called by muse, mutect2, varscan2
- UTP14A | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV100928998; called by muse, mutect2, varscan2
- VPS26A | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV99697690; called by muse, mutect2, varscan2
- WNT8A | c.423G>C p.R141S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV100843086, COSV64231242; called by muse, mutect2, varscan2
- ZC3H13 | c.2647G>T p.E883* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as COSV99668747; called by muse, mutect2, varscan2
- ZFYVE26 | c.7107G>T p.M2369I | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as COSV100720681; called by muse, mutect2, varscan2
- ZMYM3 | c.3223G>T p.V1075L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV100078281; called by muse, mutect2, varscan2
- ZNF287 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV101209416; called by muse, mutect2
- ZNF470 | c.2072A>G p.H691R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774648109, COSV100401361; called by muse, mutect2, varscan2
- ZNF479 | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100482990; called by muse, varscan2
- ZNF536 | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 18/131 reads (14%) | catalogued as COSV100834521, COSV100835689; called by muse, mutect2, varscan2
- ZNF646 | c.5090A>T p.K1697M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99762581; called by muse, mutect2, varscan2
- C4orf51 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- CAPRIN1 | c.693del p.V232Ffs*2 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- CD109 | c.2952del p.S985Afs*9 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CDKN2A | c.344_355del p.V115_A118del | In Frame Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- IGLV3-21 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by mutect2, varscan2
- MGA | c.5695_5698dup p.L1900Yfs*10 (on ENST00000219905 / NM_001164273.1; = p.L1691Yfs*10 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2, pindel
- OR1J1 | c.628_629delinsACA p.P210Tfs*60 | Frame Shift Ins (INS) | VAF 11/52 reads (21%) | called by pindel, varscan2*
- PASD1 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCDHB9 | c.379A>T p.N127Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLA1 | c.2268G>T p.M756I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- SRSF10 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SYN2 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TMEM102 | c.877_880del p.A293Lfs*25 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- WASHC2A | c.3538A>C p.S1180R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADGRG4 | c.3444T>A p.P1148= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99796385; called by muse, mutect2
- AMER2 | c.1500C>T p.P500= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100766274, COSV100766361; called by muse, mutect2
- ANK2 | c.8694T>C p.T2898= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100003576; called by muse, mutect2
- ANK2 | c.8991C>G p.S2997= | Silent (SNP) | VAF 4/95 reads (4%) | called by muse, mutect2
- AQP12A | c.237G>T p.S79= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100538937; called by muse, mutect2, varscan2
- ARHGAP19 | c.945G>T p.R315= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100363296; called by muse, mutect2
- ATP7B | c.183A>T p.T61= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99666865; called by muse, mutect2, varscan2
- AXIN1 | c.2559G>A p.K853= | Silent (SNP) | VAF 28/212 reads (13%) | catalogued as COSV99250229; called by muse, mutect2, varscan2
- CACNA1I | c.2583G>T p.L861= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100361255; called by muse, mutect2, varscan2
- CCM2 | c.732G>T p.L244= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99348062; called by muse, mutect2, varscan2
- CELSR2 | c.8319C>G p.P2773= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99604576; called by muse, mutect2, varscan2
- CERS4 | c.300G>A p.L100= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99250775; called by muse, mutect2, varscan2
- CHD5 | c.2472C>A p.T824= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99314683; called by muse, mutect2, varscan2
- COL3A1 | c.231A>T p.P77= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100483609; called by muse, mutect2, varscan2
- COL6A1 | c.2556C>T p.A852= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100720399; called by muse, mutect2, varscan2
- CRISPLD2 | c.1473G>T p.R491= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV99295952; called by muse, mutect2, varscan2
- DIAPH1 | c.3459G>A p.Q1153= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99527155; called by muse, mutect2, varscan2
- DLG5 | c.5190G>T p.R1730= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs547885540, COSV100967784; called by muse, mutect2, varscan2
- DNM3 | c.1878A>G p.L626= (on ENST00000355305 / NM_001350206.2; = p.L616= on NM_015569.5) | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100798586; called by muse, mutect2
- DOC2A | c.114G>T p.R38= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100451369; called by muse, mutect2, varscan2
- DTNA | c.1755C>A p.T585= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs759189232, COSV99314577; called by muse, mutect2, varscan2
- DUOXA1 | c.798G>T p.L266= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99973451; called by muse, mutect2
- EDA2R | c.711C>A p.A237= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99490893; called by muse, mutect2
- EPB41L3 | c.2859G>C p.T953= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100549399, COSV100549986; called by muse, mutect2, varscan2
- EPHB6 | c.1950C>G p.S650= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100844402; called by muse, mutect2
- FBXL7 | c.1104C>A p.I368= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100310598; called by muse, mutect2, varscan2
- FCRL5 | c.1647C>A p.P549= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100709250; called by muse, mutect2, varscan2
- GK2 | c.1335A>T p.P445= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV62628812; called by muse, mutect2, varscan2
- HS3ST4 | c.1095C>A p.A365= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100502541; called by muse, mutect2
- HTR1F | c.846G>A p.K282= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100138263; called by muse, mutect2
- IFIH1 | c.162G>T p.G54= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99718816; called by muse, mutect2, varscan2
- IMPG2 | c.2640G>A p.V880= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV51987142, COSV99515654, COSV99516248; called by muse, mutect2, varscan2
- KAZN | c.30C>T p.L10= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1456060542, COSV65723488; called by muse, mutect2, varscan2
- KIAA1841 | c.1191G>T p.L397= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99694136; called by muse, mutect2, varscan2
- LRIG1 | c.621A>C p.A207= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99834219; called by muse, mutect2, varscan2
- LURAP1 | c.216C>A p.I72= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100915138; called by muse, mutect2, varscan2
- MAG | c.888C>A p.T296= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100728015; called by muse, mutect2
- MAP2 | c.2439A>T p.A813= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99561389; called by muse, mutect2
- MCM3AP | c.90A>T p.P30= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99387396; called by muse, mutect2, varscan2
- MEGF10 | c.864G>T p.T288= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV57253149; called by muse, mutect2, varscan2
- MSH3 | c.3135A>T p.A1045= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99435133; called by muse, mutect2, varscan2
- MYOM3 | c.591C>T p.R197= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100293609; called by muse, mutect2
- NES | c.957C>G p.G319= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100957959; called by muse, mutect2, varscan2
- NLGN4X | c.867G>T p.V289= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99323471; called by muse, mutect2, varscan2
- NOBOX | c.990C>A p.G330= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV56193793; called by muse, mutect2, varscan2
- OR2W3 | c.552G>A p.L184= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs1192726573, COSV100831797; called by muse, mutect2, varscan2
- OR5A2 | c.555C>A p.V185= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100119829, COSV57391627; called by muse, mutect2, varscan2
- OR5AN1 | c.441G>C p.L147= | Silent (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- OR8B2 | c.882G>A p.K294= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs765394145, COSV100899474; called by muse, mutect2, varscan2
- PAK5 | c.2073C>A p.A691= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100781610; called by muse, mutect2
- PCDHGA1 | c.540G>T p.L180= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV65300648; called by muse, mutect2, varscan2
- PEAR1 | c.2148C>T p.C716= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99442173; called by muse, mutect2, varscan2
- PLEKHG1 | c.3813A>G p.K1271= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100651816; called by muse, mutect2
- PNPLA1 | c.1278C>A p.S426= (on ENST00000394571 / NM_001374623.1; = p.S331= on NM_173676.2) | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV100463545, COSV57232467; called by muse, mutect2
- PRKCB | c.720G>C p.L240= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100335051; called by muse, mutect2, varscan2
- PROSER1 | c.1218C>T p.L406= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100612988; called by muse, mutect2, varscan2
- PSD | c.2613C>T p.F871= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV50043265, COSV99193694; called by muse, mutect2, varscan2
- PTCHD1 | c.294C>G p.V98= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV101037955; called by muse, mutect2
- RAI1 | c.2190G>T p.P730= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV99884801; called by muse, mutect2
- RCOR2 | c.688C>A p.R230= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as rs760637710, COSV100036331, COSV100036335; called by muse, mutect2, varscan2
- RENBP | c.663C>T p.A221= | Silent (SNP) | VAF 23/247 reads (9%) | catalogued as COSV100129712; called by muse, mutect2
- RSPH14 | c.882G>A p.K294= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as rs1036090429, COSV99321116; called by muse, mutect2, varscan2
- RUNX1T1 | c.1485G>T p.R495= (on ENST00000265814 / NM_001198628.1; = p.R468= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV56153929, COSV99754190; called by muse, mutect2, varscan2
- SASH3 | c.123G>T p.V41= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV63556480; called by muse, mutect2, varscan2
- SCNN1D | c.1665C>T p.A555= (on ENST00000338555; = p.A719= on NM_001130413.4) | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs753216462, COSV100330242; called by muse, mutect2
- SERPINA4 | c.30G>T p.L10= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV100097412; called by muse, mutect2
- SLC17A6 | c.381C>T p.I127= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs376904844; called by muse, mutect2, varscan2
- SPDYC | c.213C>A p.V71= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV101017273; called by muse, mutect2
- SPNS3 | c.123G>T p.P41= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100337114; called by muse, mutect2, varscan2
- SPTA1 | c.3420A>G p.V1140= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100935415; called by muse, mutect2
- TBCCD1 | c.147C>T p.Y49= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100112108; called by muse, mutect2, varscan2
- TCHHL1 | c.2190C>A p.A730= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100916585; called by muse, mutect2, varscan2
- TEX2 | c.390G>T p.V130= | Silent (SNP) | VAF 27/160 reads (17%) | catalogued as COSV99366989, COSV99367408; called by muse, mutect2, varscan2
- TKTL1 | c.387C>T p.S129= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV54215082; called by muse, mutect2
- TP53BP1 | c.2907G>T p.G969= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99779988, COSV99781248; called by muse, mutect2, varscan2
- UGT2B4 | c.1152C>A p.I384= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV100522597; called by muse, mutect2, varscan2
- VCAN | c.4917A>T p.T1639= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99426946; called by muse, mutect2
- WNK2 | c.5514G>T p.V1838= (on ENST00000297954 / NM_001282394.1; = p.V1801= on NM_006648.3) | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99944120; called by muse, mutect2, varscan2
- AIFM1 | c.249+1233T>A | Intron (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99781341; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83297G>T | Intron (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851708 C>G | 3'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- AP000769.3 | chr11:65506064 del TC | 5'Flank (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- GCNT2 | c.925+27073C>A | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as COSV100297371; called by muse, mutect2, varscan2
- MIR551B | n.84G>T | RNA (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- TSHR | c.692+191G>C | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99991374, COSV99992575; called by muse, mutect2, varscan2
- VNN2 | c.*2G>T | 3'UTR (SNP) | VAF 5/33 reads (15%) | catalogued as rs1400788498, COSV100426708; called by muse, mutect2, varscan2
- Y_RNA | chr14:50091607 C>A | 3'Flank (SNP) | VAF 5/60 reads (8%) | catalogued as rs1444329593; called by muse, mutect2
